TCGA case TCGA-3H-AB3K — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e90bfe17-2e5b-47ed-b986-b3d4181f2bf6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Dead; Days to death: 1,715 days (4.7 years).

Diagnoses (3)
1. Mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9050/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 64.6 years (23,591 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Dasatinib; Days to treatment start: 52 days; Days to treatment end: 71 days; Treatment outcome: Partial Response; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 155 days; Days to treatment end: 190 days; Treatment dose: 50 Gy; Treatment outcome: Partial Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cediranib; Days to treatment start: 898 days (2.5 years); Days to treatment end: 919 days (2.5 years); Clinical trial indicator: Yes.
   Treatment given: Treatment type: Pleurodesis, NOS; Timepoint category: Prior to Procurement.
2. Metastasis of diagnosis 1 (Mesothelioma, malignant), site: Pleura, NOS. Age at diagnosis: 66.9 years (24,432 days); Days to diagnosis: 841 days (2.3 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Mesothelioma, malignant), site: Pleura, NOS. Age at diagnosis: 67.0 years (24,474 days); Days to diagnosis: 883 days (2.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (4 entries)
- Day 841 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 841 days (2.3 years).
- Day 883 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 883 days (2.4 years).
- Days to follow up: 1,715 days (4.7 years); Disease response: With Tumor.
- Imaging anatomic site: Pleura; Imaging suv max: 3.7; Timepoint: Prior to Treatment.

Molecular and laboratory tests
- Creatinine 1 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.5].

Exposures
- Occupation duration years: 30; Occupation type: Production Managers in Agriculture, Forestry and Fisheries.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3H-AB3K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 90 mg.
  Slide TCGA-3H-AB3K-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-3H-AB3K-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: Yes; Pleurodesis performed 90 days: No; Tumor status: With tumor; History asbestos exposure: No; Primary occupation: Other, please specify; Occupation primary: meat manager.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Diffuse malignant mesothelioma - NOS.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Pleurodesis < 90 days from sample procurement.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,715 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,715 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 841 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3H-AB3K-01A-11D-A39Q-01): tumor purity 0.77, ploidy 1.92, whole-genome doublings 0.
